Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0M3, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0M3-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, BIOPSY -

FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 2: UTERUS WITH CERVIX AND BILATERAL TUBES AND OVARIES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (104 GRAMS) -

- A. MODERATELY DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE, WITH SQUAMOUS METAPLASIA, FIGO GRADE 2 (see comment).
- B. TUMOR MEASURES 5 CM IN GREATEST DIMENSION.
- C. TUMOR INVADES APPROXIMATELY 53% INTO THE MYOMETRIAL THICKNESS (0.9 CM INVASION OF 1.7 CM MYOMETRIAL THICKNESS).
- D. LYMPHOVASCULAR INVASION IS PRESENT.
- E. CERVIX, NEGATIVE FOR TUMOR.
- F. LEIOMYOMATA, MEASURING UP TO 1.5 CM IN GREATEST DIMENSION.
- G. LEFT AND RIGHT OVARIES WITH ENDOSALPINGIOSIS AND PHYSIOLOGIC CHANGES, NEGATIVE FOR TUMOR.
- H. LEFT AND RIGHT FALLOPIAN TUBES, NEGATIVE FOR TUMOR.

PART 3: RIGHT PELVIC LYMPH NODES, BIOPSY -

FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).

PART 4: LEFT PELVIC LYMPH NODES, BIOPSY -

EIGHT LYMPH NODES, NEGATIVE FOR TUMOR (0/8).

PART 5: LEFT PERIAORTIC LYMPH NODES, BIOPSY -

FOUR LYMPH NODES, NEGATIVE FOR TUMOR (0/4).

ICD-0-3

Adenocarcinoma, endometrioid, NOS

8380/3

Site: Endometrium C54.1

h

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE:

Adenocarcinoma with squamous metaplasia

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Moderately differentiated (FIGO 2)

ARCHITECTURAL GRADE:

Moderately differentiated

NUCLEAR GRADE:

Grade 2

TUMOR SIZE:

Maximum dimension: 5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 90 %

DEPTH OF INVASION**:

Greater than 1/2 thickness of myometrium

ANGIOLYMPHATIC INVASION:

Yes

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 17

T STAGE, PATHOLOGIC:

pT1c

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

PMX

FIGO STAGE:

IC

COMMENT:

reviewed portions of this case and agrees with the above interpretation. Cross refer pelvic wash specimen (Pelvic Wash 1 of 3), which contained atypical cells; and gutter washing specimens which were negative for malignant cells.

Diagnosis Discrepancy		R
Primary Tumor Site Discrepancy		R
HIPAA Discrepancy		R
Prior Malignancy History		R
Dual/Synchronous Primary Noted		R
	6051311	

Source: NCI Genomic Data Commons file 5cafc89a-c2db-49f8-8757-d168118c8194 (TCGA-BG-A0M3.19AABBD8-3DC5-418E-9B62-37CF7500F174.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).